Surgical pathology report (de-identified scan), TCGA case TCGA-CA-6719, project TCGA-COAD (Colon Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CA-6719-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☐ Married		
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: lower abdominal pain; fever.
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:	/	CA 19-9	☐ Negative ☐ Positive:		
AFP	☒ Negative ☐ Positive:	/	PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the descending colon.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
COLON CANCER	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 3 N 0 M 0 Stage: II A	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
D. Hemicolectomy		
Primary Tumor		
Organ	Detailed Location	Size
Colon Tumor	Descending	3 x 2 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 3 N 0 M 0 Stage: II A		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

Date: _____ Time: _____

Preserved by: _____

Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Colon Tumor	3 x 2 x 2 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3	N 0	M 0	Stage: II 4

Notes:

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D1 40% D2 40% D3 40% D4 40% Necrosis 3%

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade			X	

Histological Diagnosis: Adenocarcinoma G2

Comments: M1: Adipose tissue, not LN. Rejected.

Source: NCI Genomic Data Commons file b0ca338a-31ab-4824-9919-1d39e390687a (TCGA-CA-6719.833D9186-0E43-498F-A698-927A968DE5A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).